Somatic mutation profile of tumor specimen TCGA-V4-A9EO-01A (aliquot TCGA-V4-A9EO-01A-12D-A39W-08) from TCGA case TCGA-V4-A9EO, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Ciliary body; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 74.4 years (27,190 days).
Specimen TCGA-V4-A9EO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ec388f0-f6cf-4a71-b7b3-6a074eef6d6a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V4-A9EO-10A (Blood Derived Normal), aliquot TCGA-V4-A9EO-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c07cc3ca-dba9-40f2-8d12-eb1504ab392d

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 12, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 23/71 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BAP1 | c.2054A>T p.E685V | Missense Mutation (SNP) | VAF 41/42 reads (98%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV56241355, COSV56242357; called by muse, mutect2, varscan2
- FHOD3 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs759696197; called by muse, mutect2, varscan2
- F5 | c.4700T>C p.I1567T | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- GMEB2 | c.218A>G p.E73G | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- KCTD19 | c.2125G>A p.D709N | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- MYO15A | c.2870C>G p.P957R | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- PARPBP | c.1189C>G p.P397A | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLEKHG2 | c.3283C>T p.P1095S | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.046); called by muse, mutect2
- PREX2 | c.2098C>T p.H700Y | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- SNX4 | c.198A>C p.E66D | Missense Mutation (SNP) | VAF 22/23 reads (96%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- TBX5 | c.743C>G p.S248* | Nonsense Mutation (SNP) | VAF 45/100 reads (45%) | called by muse, mutect2, varscan2
- WASHC5 | c.347T>C p.L116P | Missense Mutation (SNP) | VAF 70/140 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AMER3 | c.7C>T p.L3= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs1381188924; called by mutect2, varscan2
- FANCA | c.2685C>G p.P895= | Silent (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2, varscan2
- NLRP2 | c.1074C>T p.G358= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs756888601, COSV54755493; called by muse, mutect2, varscan2
- SOGA1 | c.2061C>T p.N687= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as rs528805804; called by muse, mutect2, varscan2
